Somatic mutation profile of tumor specimen TCGA-EJ-5499-01A (aliquot TCGA-EJ-5499-01A-01D-1576-08) from TCGA case TCGA-EJ-5499, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.0 years (22,286 days).
Specimen TCGA-EJ-5499-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 474bfbb0-1fe9-4d5e-9050-60eb01cdd50c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5499-10A (Blood Derived Normal), aliquot TCGA-EJ-5499-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb6e182f-4337-4d3b-ad38-9039bddeb2c5

The open-access MAF lists 34 somatic variants for this specimen: 28 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 26, Silent 6, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1BG | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs184830744, COSV54051739; called by muse, mutect2, varscan2
- ADAM29 | c.1430A>G p.D477G | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as COSV63665618; called by muse, mutect2, varscan2
- ARHGDIB | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.297); catalogued as rs544170735, COSV57455377, COSV57455689; called by muse, mutect2, varscan2
- CLEC1A | c.224A>T p.Y75F | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59532979; called by muse, mutect2, varscan2
- CPNE9 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs759711014, COSV56067715; called by muse, mutect2, varscan2
- CSF1R | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs139635308; called by muse, mutect2, varscan2
- CSF2RA | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 153/677 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62625538; called by muse, mutect2, varscan2
- CSMD2 | c.8339C>T p.P2780L | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1218799989, COSV53932353; called by muse, mutect2, varscan2
- ESS2 | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV52817636; called by muse, mutect2, varscan2
- FBXO5 | c.1214A>G p.Y405C | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV57671231; called by muse, mutect2, varscan2
- FKBP5 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV61882710; called by muse, mutect2, varscan2
- FRMPD2 | c.232C>A p.H78N | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.186); catalogued as COSV100563547, COSV59719763, COSV59720313; called by muse, mutect2, varscan2
- HECTD4 | c.1678T>C p.S560P | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV66395451; called by muse, mutect2, varscan2
- ITGAL | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 34/337 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775525981, COSV63323247; called by muse, mutect2, varscan2
- KRT6C | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as rs748113564, COSV52878772; called by muse, mutect2
- LTBR | c.625A>G p.T209A | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs778597764, COSV57439403; called by muse, mutect2, varscan2
- PAPLN | c.1054C>T p.R352W (on ENST00000554301; = p.R325W on NM_173462.4) | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs200690849, COSV53713564, COSV53720685; called by muse, mutect2, varscan2
- PCDHGC5 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.78); catalogued as rs374508743, COSV52762923; called by muse, mutect2, varscan2
- PTPRD | c.3049G>C p.D1017H | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); catalogued as COSV61962306; called by muse, mutect2, varscan2
- RPH3A | c.1354C>T p.R452W (on ENST00000389385 / NM_001143854.2; = p.R448W on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1430121018, COSV66990507; called by muse, mutect2, varscan2
- SHROOM4 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs782548063, COSV56792899; called by muse, mutect2
- SNTG2 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57994567; called by muse, mutect2, varscan2
- ST8SIA3 | c.338A>T p.N113I | Missense Mutation (SNP) | VAF 37/193 reads (19%) | PolyPhen possibly damaging (0.542); catalogued as rs756634608, COSV60654674; called by muse, varscan2
- TBC1D8B | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV52180963, COSV52182956; called by muse, mutect2, varscan2
- TNS1 | c.4363T>G p.F1455V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50724798; called by muse, mutect2, varscan2
- ZFPM2 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV65874686; called by muse, mutect2, varscan2
- CFAP54 | c.6425del p.N2142Tfs*16 | Frame Shift Del (DEL) | VAF 49/292 reads (17%) | called by mutect2, pindel, varscan2
- TRIM37 | c.1223del p.F408Sfs*26 | Frame Shift Del (DEL) | VAF 29/145 reads (20%) | called by mutect2, pindel, varscan2
- AKAP7 | c.483A>G p.G161= | Silent (SNP) | VAF 65/291 reads (22%) | catalogued as COSV63505446; called by muse, mutect2, varscan2
- CEACAM3 | c.126G>A p.P42= | Silent (SNP) | VAF 64/258 reads (25%) | catalogued as rs782786265, COSV55760722, COSV55762464; called by muse, mutect2, varscan2
- KPRP | c.36G>A p.P12= | Silent (SNP) | VAF 33/146 reads (23%) | catalogued as rs761781923, COSV64222236, COSV64223096; called by muse, mutect2, varscan2
- SLC24A1 | c.1062A>G p.V354= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs1209224761, COSV56052898; called by muse, mutect2, varscan2
- SPTB | c.5262C>A p.I1754= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV67633441; called by muse, mutect2, varscan2
- ZNF43 | c.72A>C p.A24= | Silent (SNP) | VAF 79/331 reads (24%) | catalogued as COSV61684766; called by muse, mutect2, varscan2
